FM case AD17582 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/07178645-5628-4c61-9986-db1b24b83011

Male, 64.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the stomach; primary biopsied or resected from the stomach. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
